CCDI case PBCBBW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/650f72ef-19f8-4fe1-8d67-ca0f5a1f3563

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.9 years (5,438 days).

Biospecimens (3 samples)
- Sample 0DNCAD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNCH0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNCOR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
